Gene-level copy-number profile of tumor specimen TCGA-BC-A10R-01A from TCGA case TCGA-BC-A10R, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; Tumor grade: G2; Age at diagnosis: 66.5 years (24,274 days).
Specimen TCGA-BC-A10R-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LIHC.ee6ca2fb-c381-4950-89f2-0662d9af875d.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-BC-A10R-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/c9ca3dd0-fd3d-4697-baba-c1fb40a71a6b

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 370; copy number 2: 15,201; copy number 3: 21,238; copy number 4: 17,872; copy number 5: 3,438; copy number 6: 918; copy number 7: 95; copy number 8: 7; copy number 9: 675.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-BC-A10R-01A-11D-A12Y-01): tumor purity 0.6, ploidy 3.21, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 777 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:237,042,184–237,833,988, 1 gene, copy number 7 (within-gene range 6–11): RYR2.
- chr1:237,471,119–241,677,376, 63 genes, copy number 7–8 (within-gene range 6–8) (broad region; genes not listed).
- chr2:200,678,233–200,830,116, 8 genes, copy number 7: AOX3P, AOX3P-AOX2P, LINC01792, AOX2P, RNU1-133P, BZW1-AS1, BZW1, RNU6-31P.
- chr6:3,177,044–3,457,050, 6 genes, copy number 7 (within-gene range 5–7): TUBB2BP1, LINC02525, TUBB2B, PSMG4, SLC22A23, AL445309.1.
- chr6:26,087,281–26,189,112, 11 genes, copy number 7: HFE, H4C3, H1-6, H2BC4, H2AC6, H1-4, H2BC5, AL353759.1, LARP1P1, H2BC6, H4C4.
- chr7:21,900,899–22,357,154, 2 genes, copy number 7 (within-gene range 4–7): CDCA7L, RAPGEF5.
- chr10:44,712–38,783,108, 675 genes, copy number 9 (broad region; genes not listed).
- chr22:49,718,053–49,890,080, 11 genes, copy number 7 (within-gene range 5–7): AL023802.1, RN7SKP252, RPL5P35, BRD1, Z98885.3, Z98885.1, Z98885.2, AL117328.1, Metazoa_SRP, AL117328.2, ZBED4.

Autosomal genes at a single copy (total copy number 1): 370. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
